CTSP case CTSP-AD05 — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f9c586d5-cc4b-46f6-bdea-067ecbb870a4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1948; Vital status: Dead; Days to death: 12 days; Year of death: 2009; Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 61.0 years (22,284 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage IV; Days to last follow up: 12 days; Best overall response: No Response; Ann Arbor extranodal involvement: No; Double expressor lymphoma: Yes; Double hit lymphoma: No; International Prognostic Index (IPI): High Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 131 kg; Height: 168 cm; BMI: 46.4.

Biospecimens (1 sample)
- Sample DLBCL11309-sample: Sample type: Tumor; Tissue type: Tumor.
